Somatic mutation profile of tumor specimen 0DSG24 from CCDI case PBCIAR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.3 years (4,486 days).
Specimen 0DSG24: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe031690-bfd8-44a9-ada1-f363af455264.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSG2L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17924bd2-23f1-40a2-916c-965212079d68

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 3, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 320/858 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs121908738, CM900008; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- DDX3X | c.974G>A p.R325H (on ENST00000399959; = p.R326H on NM_001356.5) | Missense Mutation (SNP) | VAF 62/1356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs797045025, CM158024, COSV101302329; ClinVar: pathogenic; called by muse, mutect2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 102/524 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARL15 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 71/588 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374674965; called by muse, mutect2, varscan2
- ASB13 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 63/984 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs879432449, COSV100731335; called by muse, mutect2
- CYB561 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 429/935 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100669156; called by muse, mutect2, varscan2
- DNAH17 | c.6941C>T p.T2314M | Missense Mutation (SNP) | VAF 171/521 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs753233839; called by muse, mutect2, varscan2
- DUSP28 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 94/412 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs1023226275; called by muse, mutect2, varscan2
- MAGEB3 | c.951A>T p.R317S | Missense Mutation (SNP) | VAF 106/740 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV100854603, COSV100854820; called by mutect2, varscan2
- MALRD1 | c.5072dup p.L1691Ffs*15 | Frame Shift Ins (INS) | VAF 158/1158 reads (14%) | catalogued as rs775300614; called by mutect2, varscan2
- NGEF | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 214/498 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1050106677; called by muse, mutect2, varscan2
- PTCH1 | c.279C>G p.Y93* | Nonsense Mutation (SNP) | VAF 965/1006 reads (96%) | catalogued as CM014378; called by muse, mutect2, varscan2
- RPP40 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 170/793 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1367162388; called by muse, mutect2, varscan2
- RPS6KA3 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 578/1290 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1431378578; called by muse, mutect2, varscan2
- SERPIND1 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 38/924 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1247785389; called by muse, mutect2
- VILL | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 358/784 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs372162890; called by muse, mutect2, varscan2
- AFF2 | c.582A>T p.E194D | Missense Mutation (SNP) | VAF 40/1096 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2
- FOLH1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 37/835 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.403); called by muse, mutect2
- GLS | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 30/816 reads (4%) | called by muse, mutect2
- HOXA10 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.129); called by muse, mutect2
- KDM6A | c.3352del p.L1118Ffs*2 | Frame Shift Del (DEL) | VAF 458/960 reads (48%) | called by mutect2, varscan2
- NKX3-2 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 148/556 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SOX3 | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 400/777 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNXB | c.11407G>A p.E3803K (on ENST00000647633; = p.E3556K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 205/791 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UNC13C | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 189/714 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZC3H12B | c.2059G>T p.G687W | Missense Mutation (SNP) | VAF 86/615 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PLG | c.1656C>T p.Y552= | Silent (SNP) | VAF 368/1270 reads (29%) | catalogued as rs113153850; called by muse, mutect2, varscan2
- SOX17 | c.762G>T p.A254= | Silent (SNP) | VAF 88/446 reads (20%) | catalogued as rs914820464, COSV52025064, COSV99810534; called by muse, mutect2, varscan2
- USH2A | c.6678C>T p.C2226= | Silent (SNP) | VAF 312/739 reads (42%) | called by muse, mutect2, varscan2
- ACAD8 | c.567+9G>A | Intron (SNP) | VAF 99/731 reads (14%) | catalogued as rs770576967; called by muse, mutect2, varscan2
- CREB5 | c.465-32610G>C | Intron (SNP) | VAF 194/914 reads (21%) | called by muse, mutect2, varscan2
- CT55 | c.-98C>G | 5'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2
